TCGA case TCGA-41-3915 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43d98306-8b1f-4840-a1a0-146ba0c36400

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 360 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 49.0 years (17,880 days); Year of diagnosis: 2010; Method of diagnosis: Incisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Days to treatment start: 27 days; Days to treatment end: 71 days; Treatment dose: 6,000 cGy; Chemo concurrent to radiation: Yes; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 27 days; Days to treatment end: 71 days; Number of cycles: 1; Treatment dose: 6,880 mg; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 115 days; Number of cycles: 3; Treatment dose: 5,200 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 320; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 202 days; Days to treatment end: 289 days; Number of cycles: 4; Treatment dose: 8,000 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 49.7 years (18,168 days); Days to diagnosis: 288 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 301 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 184 days; Disease response: With Tumor.
- Day 288 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional.
- Days to follow up: 360 days; Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-41-3915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-41-3915-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 0.
  Slide TCGA-41-3915-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 0.
- Sample TCGA-41-3915-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-41-3915-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent Chemoradiation.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: temodar.
- Radiation treatment: Radiation type other: Intensity modulated radiation; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent chemoradiation.
- Follow-up form, New tumor event: New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 360 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 360 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 288 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-41-3915-01A-01D-1224-01): tumor purity 0.77, ploidy 1.83, whole-genome doublings 0.
